Somatic mutation profile of tumor specimen TARGET-10-PATEVL-09A (aliquot TARGET-10-PATEVL-09A-01D) from TARGET case TARGET-10-PATEVL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,228 days).
Specimen TARGET-10-PATEVL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e094c11-18cc-4e09-8e5a-6564088bcdf8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATEVL-10A (Blood Derived Normal), aliquot TARGET-10-PATEVL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc1102e8-6552-407a-86ca-120185e0c6ec

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Intron 2, 3'UTR 1, RNA 1, Frame Shift Ins 1, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CFAP61 | c.951G>T p.Q317H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV55652190; called by muse, mutect2, varscan2
- MDM1 | c.1058C>A p.T353K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM142481, COSV100291795, COSV57449588; called by muse, mutect2, varscan2
- NIPBL | c.8339G>T p.S2780I | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV56971376; called by muse, mutect2, varscan2
- RHEBL1 | c.67G>C p.A23P | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV56505196, COSV99988020; called by muse, mutect2, varscan2
- SARDH | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs764863613, COSV64101436; called by muse, varscan2
- WT1 | c.1091_1092insCGTTC p.T365Vfs*74 | Frame Shift Ins (INS) | VAF 8/16 reads (50%) | catalogued as COSV100187393, COSV60065578, COSV60066574, COSV60067966, COSV60069180, COSV60069294, COSV60069675, COSV60071329, COSV60072717, COSV60072799, COSV60073173, COSV60073318, COSV60074036, COSV60082207, COSV60083929, COSV…; called by mutect2, varscan2
- ZNF771 | c.842A>G p.H281R | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60008788; called by muse, mutect2, varscan2
- IGHV1-69D | c.352_353insGGGGGTG p.*118delinsGG* | Nonsense Mutation (INS) | VAF 12/60 reads (20%) | called by mutect2, pindel*, varscan2*
- PRSS54 | c.696C>A p.F232L | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UTP4 | c.24_29dup p.V9_R10dup | In Frame Ins (INS) | VAF 30/70 reads (43%) | called by mutect2, varscan2
- JMY | c.1257A>G p.Q419= | Silent (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- NOP2 | c.222T>C p.P74= | Silent (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- KRT18 | c.948+34C>A | Intron (SNP) | VAF 19/27 reads (70%) | called by muse, mutect2, varscan2
- OR2T2 | c.*21G>T | 3'UTR (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- PIPSL | n.454C>T | RNA (SNP) | VAF 68/126 reads (54%) | catalogued as rs756748645; called by muse, varscan2
- TNXB | c.2358+1759C>G | Intron (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
